Somatic mutation profile of tumor specimen C3L-01046-01 (aliquot CPT0127480007) from CPTAC case C3L-01046, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.9 years (18,595 days).
Specimen C3L-01046-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Temporal Cortex; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10060030-c79b-4c7f-a497-c13e372e66d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01046-31 (Blood Derived Normal), aliquot CPT0128570002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75e9415a-de98-4ffc-9f53-428f764da782

The open-access MAF lists 59 somatic variants for this specimen: 38 protein-altering or splice-affecting, 15 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 15, Intron 2, Splice Site 2, Frame Shift Del 2, Nonsense Mutation 2, 3'Flank 2, RNA 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.209+2T>C p.X70_splice | Splice Site (SNP) | VAF 14/48 reads (29%) | hotspot (GDC flag); catalogued as rs878853937, CS132271, CS1513174, COSV64289116, COSV64290075, COSV64293495; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL1A1 | c.1299C>T p.S433= | Splice Region (SNP) | VAF 35/166 reads (21%) | catalogued as rs776229611; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DENND2C | c.929A>G p.Y310C | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1235928425; called by muse, mutect2, varscan2
- DGKE | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757585573; called by muse, mutect2, varscan2
- EGFL7 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as rs745614827; called by muse, mutect2, varscan2
- FER1L5 | c.3545G>A p.R1182H (on ENST00000623019; = p.R1155H on NM_001293083.2) | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775780731, COSV101208890; called by muse, mutect2, varscan2
- FRMD7 | c.2018C>T p.P673L | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs947185883; called by muse, mutect2
- GABRA6 | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 51/282 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749910403; called by muse, mutect2, varscan2
- IBSP | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs750881428; called by muse, mutect2, varscan2
- INPP4B | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs777966937, COSV53720995; called by muse, mutect2, varscan2
- INPP5D | c.3170C>T p.S1057L (on ENST00000445964 / NM_001017915.3; = p.S1056L on NM_005541.5) | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs758989076, COSV100856444; called by muse, mutect2, varscan2
- LRRC2 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs142071651; called by muse, mutect2, varscan2
- MUC12 | c.12365C>T p.A4122V (on ENST00000379442; = p.A3979V on NM_001164462.1) | Missense Mutation (SNP) | VAF 127/3058 reads (4%) | SIFT tolerated (1); catalogued as rs751164624, COSV65183213; called by muse, mutect2
- MYH4 | c.5147G>A p.R1716H | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs746179757; called by muse, mutect2, varscan2
- NF1 | c.3822_3823del p.F1275Pfs*8 | Frame Shift Del (DEL) | VAF 68/362 reads (19%) | catalogued as rs1555615472; called by pindel, varscan2
- NOD2 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 62/326 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs374128251; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPR3 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs1011584298, COSV54088924; called by muse, mutect2, varscan2
- OR2C3 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs147306837, COSV63574800; called by muse, mutect2
- OR52M1 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs145046460; called by muse, mutect2, varscan2
- PARPBP | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 36/270 reads (13%) | catalogued as rs1001669268; called by muse, mutect2, varscan2
- RDH8 | c.259G>A p.V87M (on ENST00000651512; = p.V67M on NM_015725.4) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs545999307, COSV50674739; called by muse, mutect2, varscan2
- SLC6A11 | c.1823C>T p.T608I | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs145036467; called by muse, mutect2, varscan2
- STEAP4 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs758443467, COSV57328006, COSV57330266; called by muse, mutect2, varscan2
- TGFB1 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs753287325, COSV55726156; called by muse, mutect2, varscan2
- TRPC7 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.785); catalogued as COSV100725356, COSV61465568; called by muse, mutect2, varscan2
- CCDC88A | c.281T>G p.L94W | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CELSR1 | c.2386G>A p.V796M | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DPYSL5 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERAP1 | c.920-1G>T p.X307_splice | Splice Site (SNP) | VAF 45/271 reads (17%) | called by muse, mutect2, varscan2
- GLYAT | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.011); called by muse, mutect2
- NF1 | c.5824A>T p.K1942* (on ENST00000358273 / NM_001042492.3; = p.K1921* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 38/174 reads (22%) | called by muse, mutect2, varscan2
- NUP107 | c.1840G>C p.E614Q | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.181); called by muse, mutect2
- SMG8 | c.1401G>T p.L467F | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- UTP20 | c.3434T>G p.I1145S | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WASH6P | c.1281C>A p.N427K | Missense Mutation (SNP) | VAF 106/1456 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); called by muse, mutect2
- ZBTB38 | c.1483A>G p.K495E | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF112 | c.550A>T p.R184W (on ENST00000337401 / NM_001083335.2; = p.R178W on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- ZNF804B | c.1268del p.N423Mfs*6 | Frame Shift Del (DEL) | VAF 37/272 reads (14%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.6939G>A p.P2313= | Silent (SNP) | VAF 33/137 reads (24%) | catalogued as rs201009629, COSV101316249; called by muse, mutect2, varscan2
- CNGB3 | c.738C>T p.T246= | Silent (SNP) | VAF 21/427 reads (5%) | catalogued as rs781628736, COSV60696152, COSV60697184; ClinVar: uncertain significance; called by muse, mutect2
- DOT1L | c.2733G>A p.S911= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as rs1262829365; called by muse, mutect2
- ETS2 | c.828C>T p.H276= | Silent (SNP) | VAF 34/175 reads (19%) | catalogued as rs566869068; called by muse, mutect2, varscan2
- FSHR | c.1683C>T p.I561= | Silent (SNP) | VAF 54/348 reads (16%) | catalogued as rs757713421, COSV58623930; called by muse, mutect2, varscan2
- GREB1 | c.828C>T p.N276= | Silent (SNP) | VAF 21/198 reads (11%) | catalogued as rs150918268; called by muse, mutect2, varscan2
- KRT76 | c.1074C>T p.R358= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs779105282; called by muse, mutect2, varscan2
- LDB3 | c.2073C>T p.H691= | Silent (SNP) | VAF 78/288 reads (27%) | catalogued as rs45486293; ClinVar: likely benign; called by muse, mutect2, varscan2
- MCM9 | c.1176C>T p.D392= | Silent (SNP) | VAF 41/191 reads (21%) | called by muse, mutect2, varscan2
- OR2G2 | c.678C>T p.H226= | Silent (SNP) | VAF 61/288 reads (21%) | catalogued as rs779772045, COSV60740879; called by muse, mutect2, varscan2
- OR6V1 | c.181C>T p.L61= | Silent (SNP) | VAF 45/292 reads (15%) | called by muse, mutect2, varscan2
- PDILT | c.1290G>A p.L430= | Silent (SNP) | VAF 61/271 reads (23%) | catalogued as COSV56699758, COSV56701442; called by muse, mutect2, varscan2
- SOAT1 | c.1389C>T p.A463= | Silent (SNP) | VAF 24/338 reads (7%) | called by muse, mutect2
- SYT5 | c.681G>C p.R227= | Silent (SNP) | VAF 30/162 reads (19%) | catalogued as rs1407278821; called by muse, mutect2, varscan2
- ZSCAN10 | c.1035C>T p.D345= (on ENST00000252463; = p.D400= on NM_032805.3) | Silent (SNP) | VAF 35/175 reads (20%) | catalogued as COSV52968241; called by muse, mutect2, varscan2
- AC027559.1 | n.240C>T | RNA (SNP) | VAF 28/239 reads (12%) | catalogued as rs1293617108; called by muse, mutect2, varscan2
- BAZ2B | c.2832+27_2832+28del | Intron (DEL) | VAF 22/110 reads (20%) | called by mutect2, pindel, varscan2
- FMR1 | c.*1888G>C | 3'UTR (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- MEF2A | chr15:99716527 G>A | 3'Flank (SNP) | VAF 42/208 reads (20%) | catalogued as rs768872108; called by muse, mutect2, varscan2
- RPL37AP1 | chr20:44462059 G>A | 3'Flank (SNP) | VAF 37/242 reads (15%) | catalogued as rs1311820451; called by muse, mutect2, varscan2
- TMEM132D | c.1444-24C>A | Intron (SNP) | VAF 7/60 reads (12%) | catalogued as COSV67160974; called by muse, varscan2
